Surgical pathology report (de-identified scan), TCGA case TCGA-DC-4749, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-4749-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Old male with sigmoid colon cancer, no adjuvant chemoradiation.

Specimens Submitted:

- 1: SP: Recto sigmoid colon
- 2: SP: Proximal anastomotic ring
- 3: SP: Distal anastomotic ring

DIAGNOSIS:

1. COLON, RECTOSIGMOID; RESECTION:
- INVASIVE ADENOCARCINOMA, MODERATELY TO POORLY DIFFERENTIATED.
- TUMOR LOCATION: RECTOSIGMOID.
- TUMOR SIZE: LENGTH IS 4.0 CM, WIDTH IS 3.5 CM, MAXIMAL THICKNESS IS 1.5 CM.
- GROSS CONFIGURATION: FUNGATING.
- PREEXISTING POLYP (AT THE SITE OF THE CARCINOMA): NOT IDENTIFIED.
- TUMOR INVASION: INVASION INTO SUPERFICIAL MUSCULARIS PROPRIA.
- GROSS TUMOR PERFORATION: NOT IDENTIFIED.
- SEROSAL INVOLVEMENT: NOT IDENTIFIED.
- VASCULAR INVASION: IDENTIFIED.
- PERINEURAL INVASION: NOT IDENTIFIED.
- SURGICAL MARGINS: FREE OF TUMOR.
- POLYPS (AWAY FROM THE CARCINOMA): NOT IDENTIFIED.
- NON-NEOPLASTIC BOWEL: UNREMARKABLE.
- THE PATHOLOGIC STAGE IS (AJCC): PT2
- LYMPH NODES: NUMBER WITH METASTASES: 0, NUMBER EXAMINED: 16.
- THE PATHOLOGIC STAGE IS (AJCC): pN0
2. COLON, PROXIMAL ANASTOMOTIC RING; EXCISION:
- BENIGN SEGMENT OF COLON.
3. RECTUM, DISTAL ANASTOMOTIC RING; EXCISION:
- BENIGN SEGMENT OF RECTUM.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

[page 2 of 3]
Special Studies: Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	
	RECUT	

Gross Description:

1) The specimen is received in formalin, labeled "Recto sigmoid colon" and consists of a piece of large bowel measuring 14.0 cm in length and 6.5 cm in circumference. The specimen has one stapled end arbitrarily designated proximal with an opened end designated distal. The serosa is pink-tan and smooth with attached yellow lobulated adipose tissue. On sectioning a 4.0 x 3.5 x 1.5 cm fungating, polypoid tumor is identified, 3.5 cm from the distal margin and 7.0 cm from the proximal margin. The depth of invasion is 0.5 cm. The remaining mucosa is tan-pink and with the normal folds with multiple minute polypoid structures identified. Pericolic adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. A portion of the tumor is previously taken for TFS.

Summary of sections:
PM-- proximal margin
DM-- distal margin
T-- tumor (blocked out)
P-- polypoid structures
U--uninvolved
LN-- lymph node

2) The specimen is received in formalin, labeled "Proximal anastomotic ring" and consists of a ring of pink tan soft tissue measuring 1.5 x 1.5x 0.9 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U--undesignated

3) The specimen is received in formalin, labeled "Distal anastomotic ring" and consists of a ring of pink tan soft tissue measuring 1.5 x 1.5 x 0.83 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U--undesignated

** Continued on next page **

[page 3 of 3]
Summary of Sections:

Part 1: SP: Recto sigmoid colon

Block	Sect.	Site	PCs
5		ADD	5
2		DM	4
13		LN	26
1		P	2
1		PM	5
5		T	5
3		U	

Part 2: SP: Proximal anastomotic ring

Block	Sect.	Site	PCs
1		u	10

Part 3: SP: Distal anastomotic ring

Block	Sect.	Site	PCs
1		u	10

** End of Report **

Source: NCI Genomic Data Commons file 12161adc-74fd-47f8-a7e2-c54f4bde7f15 (TCGA-DC-4749.5AE4E8BD-DE96-4445-A81C-923C3898AB67.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).